Somatic mutation profile of tumor specimen TCGA-AR-A24M-01A (aliquot TCGA-AR-A24M-01A-11D-A167-09) from TCGA case TCGA-AR-A24M, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 38.7 years (14,119 days).
Specimen TCGA-AR-A24M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 613b7d68-ab12-4980-88df-e313f5ca9dc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24M-10A (Blood Derived Normal), aliquot TCGA-AR-A24M-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59f4a09c-1db0-455d-9085-a03d418391a8

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CROCC | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs745666217, COSV65012353; called by muse, mutect2, varscan2
- MBNL2 | c.652T>A p.C218S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59121290; called by muse, mutect2, varscan2
- MRE11 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60577273; called by muse, mutect2, varscan2
- PHRF1 | c.4317G>C p.E1439D (on ENST00000264555 / NM_001286581.2; = p.E1438D on NM_020901.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV99199514; called by muse, mutect2, varscan2
- PIK3R1 | c.1529A>T p.E510V (on ENST00000521381 / NM_181523.3; = p.E240V on NM_181504.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57131162; called by muse, mutect2, varscan2
- PLD5 | c.664T>C p.S222P (on ENST00000442594; = p.S160P on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV59148048; called by muse, mutect2, varscan2
- PLK3 | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.516); catalogued as COSV59499991; called by muse, mutect2, varscan2
- SLC25A36 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.061); catalogued as COSV60782038; called by muse, mutect2, varscan2
- UTP3 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV54661189; called by muse, mutect2, varscan2
- SLC35B2 | c.329_331delinsAG p.L110Qfs*15 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by pindel, varscan2*
- ABCA3 | c.2283G>A p.T761= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs757924380, COSV57054309; called by muse, mutect2, varscan2
- CRB1 | c.1488C>A p.V496= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100957684; called by muse, mutect2, varscan2
- GOLGB1 | c.2847G>A p.V949= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs759219856, COSV61466316; called by muse, mutect2, varscan2
- MARCKSL1 | c.174C>T p.A58= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs142561179; called by muse, mutect2, varscan2
- TBCA | c.231T>C p.D77= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100115850; called by muse, mutect2
- TTC6 | c.363T>C p.Y121= (on ENST00000267368; = p.Y1487= on NM_001310135.3) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs577357532, COSV57449422; called by muse, mutect2, varscan2
- ZNF622 | c.684C>T p.D228= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs961943821, COSV58073901; called by muse, mutect2, varscan2
- NFYC | c.387+1123del | Intron (DEL) | VAF 10/41 reads (24%) | catalogued as COSV58127374; called by mutect2, pindel*, varscan2
